Somatic mutation profile of tumor specimen TARGET-40-NAAWFT-01A (aliquot TARGET-40-NAAWFT-01A-01D) from TARGET case TARGET-40-NAAWFT, project TARGET-OS (Osteosarcoma). Sex at birth: female; Primary diagnosis: Osteosarcoma, NOS; Age at diagnosis: 28.0 years (10,220 days).
Specimen TARGET-40-NAAWFT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68c775cd-7658-4aeb-9b4d-123ef0f86087.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAWFT-10A (Blood Derived Normal), aliquot TARGET-40-NAAWFT-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa266230-fd67-46b9-b1f4-31ae740bbf79

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PLA2G4C | c.1202C>T p.T401M | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs750067126; called by muse, mutect2, varscan2
- ATRX | c.2169_2170del p.E723Dfs*9 | Frame Shift Del (DEL) | VAF 64/189 reads (34%) | called by pindel, varscan2
- CELSR3 | c.1672G>A p.V558M | Missense Mutation (SNP) | VAF 52/82 reads (63%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- HIVEP2 | c.2104A>T p.S702C | Missense Mutation (SNP) | VAF 103/248 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SLC38A10 | c.2666C>T p.S889F | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- SNTG2 | c.1084C>T p.L362F | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.383); called by muse, mutect2, varscan2
